Somatic mutation profile of tumor specimen TCGA-44-7672-01A (aliquot TCGA-44-7672-01A-11D-2063-08) from TCGA case TCGA-44-7672, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 52.6 years (19,200 days).
Specimen TCGA-44-7672-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2b214ff-9f66-49c3-b4e6-540c7c4d9b89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-7672-10A (Blood Derived Normal), aliquot TCGA-44-7672-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1309f4e1-0533-4d1c-aefb-1657da687007

The open-access MAF lists 167 somatic variants for this specimen: 122 protein-altering or splice-affecting, 44 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 44, Nonsense Mutation 9, Frame Shift Del 5, Splice Site 3, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 27/54 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA1 | c.3734A>G p.E1245G | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66069327; called by muse, mutect2, varscan2
- ABCB1 | c.805G>A p.G269R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55954965, COSV55959459; called by muse, mutect2
- ACTN2 | c.738G>T p.M246I | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.764); catalogued as COSV63977371, COSV63977464; called by muse, mutect2
- ADGRE1 | c.2239G>T p.E747* | Nonsense Mutation (SNP) | VAF 28/164 reads (17%) | catalogued as COSV51679175; called by muse, mutect2, varscan2
- ADK | c.519G>A p.W173* (on ENST00000286621; = p.W156* on NM_001123.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | catalogued as COSV54215495; called by muse, mutect2
- AK7 | c.916A>T p.R306* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV50878456; called by muse, mutect2, varscan2
- ALPG | c.326C>A p.P109Q | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54967568; called by muse, mutect2
- ALX1 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57492286, COSV57493680; called by muse, mutect2, varscan2
- AMBP | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs988156509, COSV54325085; called by muse, mutect2, varscan2
- ANO3 | c.2680C>A p.P894T | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56802813; called by muse, mutect2, varscan2
- ATRX | c.5834G>A p.G1945E | Missense Mutation (SNP) | VAF 50/478 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV64881057; called by muse, mutect2, varscan2
- BMP15 | c.1069T>G p.C357G | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53141620; called by muse, mutect2, varscan2
- BRINP1 | c.375C>A p.Y125* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV56299739, COSV56309285; called by muse, mutect2, varscan2
- CACNG6 | c.689T>A p.I230N (on ENST00000252729 / NM_145814.1; = p.I159N on NM_031897.2) | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV53167722; called by muse, mutect2, varscan2
- CASP3 | c.831C>G p.H277Q | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.198); catalogued as COSV57725598; called by muse, mutect2
- CCDC70 | c.303G>T p.K101N | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV54430773; called by muse, mutect2, varscan2
- CCDC89 | c.519G>T p.E173D | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.526); catalogued as COSV57034574; called by muse, mutect2, varscan2
- CDC123 | c.985-2A>G p.X329_splice | Splice Site (SNP) | VAF 12/56 reads (21%) | catalogued as rs1259058248, COSV55399320; called by muse, mutect2, varscan2
- CDH22 | c.1871C>G p.P624R | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.694); catalogued as COSV64839040; called by muse, mutect2, varscan2
- CHPF | c.1445C>G p.T482S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.145); catalogued as COSV60536261; called by muse, mutect2, varscan2
- CHRNA1 | c.950C>A p.P317H (on ENST00000261007 / NM_001039523.3; = p.P292H on NM_000079.4) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53684466; called by muse, mutect2, varscan2
- CLVS2 | c.732C>G p.I244M | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV51567380, COSV99253546; called by muse, mutect2
- CMYA5 | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs939322701, COSV101484237; called by muse, mutect2, varscan2
- COL19A1 | c.1253G>T p.G418V | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV59565823, COSV59582426; called by muse, mutect2
- COL4A2 | c.3668G>A p.G1223D | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64632075; called by muse, mutect2
- COL4A6 | c.1573G>T p.G525C | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57873893; called by muse, mutect2
- CSMD3 | c.9079C>A p.L3027I (on ENST00000297405 / NM_001363185.1; = p.L2858I on NM_052900.3) | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV52272316; called by muse, mutect2, varscan2
- DDX53 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs903053245, COSV60069737; called by muse, mutect2
- FAF2 | c.1118G>T p.R373L | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56130479, COSV56132537; called by muse, mutect2
- FAT3 | c.2049C>A p.C683* | Nonsense Mutation (SNP) | VAF 14/81 reads (17%) | catalogued as COSV53155653; called by muse, mutect2, varscan2
- FBN2 | c.4471+1G>A p.X1491_splice | Splice Site (SNP) | VAF 3/34 reads (9%) | catalogued as COSV52535288; called by muse, mutect2
- GCNT4 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV59280879, COSV59281465; called by muse, mutect2
- GDA | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52996475; called by muse, mutect2, varscan2
- GLIPR1L2 | c.452G>T p.C151F | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV57555365; called by muse, mutect2, varscan2
- GPATCH8 | c.2600G>T p.R867L | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.09); catalogued as COSV59197066; called by muse, mutect2
- GPR31 | c.835C>A p.P279T | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100834165; called by muse, mutect2
- GPR78 | c.866C>A p.A289D | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); catalogued as COSV66763734; called by muse, mutect2, varscan2
- GRIK2 | c.1432T>C p.Y478H | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59759243; called by muse, mutect2, varscan2
- IFNA6 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV66506670; called by muse, mutect2, varscan2
- IL1RAPL1 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV56286690; called by muse, mutect2
- IQSEC2 | c.1717C>T p.R573C (on ENST00000642864 / NM_001111125.3; = p.R368C on NM_015075.2) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.998); catalogued as COSV64727395; called by muse, varscan2
- IRX3 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV61668647; called by muse, mutect2, varscan2
- KCNT2 | c.1696C>A p.Q566K | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.028); catalogued as COSV54099605; called by muse, mutect2, varscan2
- KIAA1109 | c.14407A>T p.N4803Y | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52686729; called by mutect2, varscan2
- LMAN1 | c.206A>T p.H69L | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV51828591; called by muse, mutect2, varscan2
- LRRC32 | c.477C>A p.N159K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52634470; called by muse, mutect2, varscan2
- LTBP1 | c.2167G>T p.A723S (on ENST00000404816 / NM_206943.4; = p.A397S on NM_000627.4) | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV100617753; called by muse, mutect2
- MAGEA12 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as rs1556833497, COSV63294552, COSV63294755; called by muse, mutect2
- MOXD1 | c.319C>T p.H107Y | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100382023, COSV60946729; called by muse, mutect2
- MYO16 | c.241A>C p.K81Q | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.373); catalogued as COSV51810288; called by muse, mutect2
- NALCN | c.3602C>A p.A1201D | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV51955222; called by muse, mutect2, varscan2
- NLRP12 | c.1394C>A p.A465E | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60743284, COSV60752320; called by muse, mutect2, varscan2
- NOTCH1 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 12/219 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs763187824, COSV53073935; ClinVar: uncertain significance; called by muse, mutect2
- OR2T12 | c.825C>G p.F275L | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs1449066902, COSV100527835, COSV58778952; called by muse, mutect2, varscan2
- OR52J3 | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100984915, COSV66747581; called by muse, mutect2, varscan2
- OR5T3 | c.278T>C p.M93T | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as rs753634306, COSV57382007; called by muse, mutect2, varscan2
- OR8S1 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV100043666, COSV59600095; called by muse, mutect2, varscan2
- OR9Q1 | c.452C>A p.A151D | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV59045002; called by muse, mutect2, varscan2
- PARD3B | c.2207G>T p.G736V (on ENST00000406610 / NM_001302769.2; = p.G674V on NM_152526.6) | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62523834; called by muse, mutect2, varscan2
- PCDHB11 | c.2095T>C p.S699P | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.836); catalogued as COSV100697192, COSV61313390; called by muse, mutect2
- PCDHB3 | c.2153G>T p.R718M | Missense Mutation (SNP) | VAF 21/275 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as COSV50609104; called by muse, mutect2
- PCDHB4 | c.671C>G p.T224R | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV52025507; called by muse, mutect2, varscan2
- PCDHB4 | c.1121C>A p.S374Y | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52025519; called by muse, mutect2, varscan2
- PCDHB8 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 29/466 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV50779500; called by muse, mutect2
- PCDHGB6 | c.169A>T p.S57C | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV54004672; called by muse, mutect2, varscan2
- PCK1 | c.1288G>A p.G430S | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV60130264; called by muse, mutect2, varscan2
- PDK3 | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64794098; called by muse, mutect2, varscan2
- PLK1 | c.461G>T p.R154L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55623732; called by muse, mutect2, varscan2
- PRKACA | c.666G>T p.W222C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58069598; called by muse, mutect2, varscan2
- PRKAG3 | c.1266G>T p.R422S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV99292059; called by muse, mutect2, varscan2
- PRR5L | c.649G>T p.V217L | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100287258; called by muse, mutect2
- PSG6 | c.781T>A p.C261S | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs752862323, COSV51836081; called by muse, mutect2
- PTPRZ1 | c.6848T>A p.V2283E | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66442876; called by muse, mutect2, varscan2
- PXDNL | c.3956G>T p.R1319L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV62478813, COSV62502615; called by muse, mutect2
- PYHIN1 | c.606C>A p.H202Q | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63723568, COSV63723785, COSV99058728; called by muse, mutect2, varscan2
- RANBP6 | c.3058A>G p.T1020A | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV52390884; called by muse, mutect2, varscan2
- RBBP8 | c.970C>T p.R324* | Nonsense Mutation (SNP) | VAF 14/103 reads (14%) | catalogued as rs373907735; called by muse, mutect2, varscan2
- RBM19 | c.2290A>T p.K764* | Nonsense Mutation (SNP) | VAF 19/134 reads (14%) | catalogued as rs931009611, COSV55696557; called by muse, mutect2, varscan2
- RFX6 | c.813C>A p.H271Q | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60587852; called by muse, mutect2, varscan2
- RXFP3 | c.538C>A p.R180S | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57506028, COSV57507322; called by muse, mutect2
- RYR1 | c.9015G>T p.L3005F | Missense Mutation (SNP) | VAF 61/269 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV62106329; called by muse, mutect2, varscan2
- SATB2 | c.869A>T p.Q290L | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV53490439; called by muse, mutect2
- SCAMP3 | c.663G>C p.M221I | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.163); catalogued as COSV56946881; called by muse, mutect2
- SDC2 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56230047; called by muse, mutect2, varscan2
- SEC14L1 | c.753G>T p.L251F | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101171129; called by muse, mutect2
- SEC14L1 | c.754A>T p.T252S | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.034); catalogued as COSV101171130; called by muse, mutect2
- SELENBP1 | c.827G>T p.R276L | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as rs765918794, COSV64373984, COSV64374208; called by muse, mutect2, varscan2
- SEMA5A | c.2275G>T p.G759C | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66802117; called by muse, mutect2
- SEMA6B | c.1124C>A p.P375H | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56705417; called by muse, mutect2, varscan2
- SI | c.3519G>A p.M1173I | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1447015883, COSV52293333, COSV52298702; called by muse, mutect2
- SIAH3 | c.387G>T p.Q129H | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.251); catalogued as rs1300974455, COSV101247962; called by muse, mutect2
- SLC2A9 | c.1301C>A p.P434Q | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53325784; called by muse, mutect2, varscan2
- SLC5A8 | c.1201G>T p.A401S | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV73311010; called by muse, mutect2
- SOX5 | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 17/275 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58642308; called by muse, mutect2
- SPEF2 | c.727-2A>G p.X243_splice | Splice Site (SNP) | VAF 8/100 reads (8%) | catalogued as COSV56799453; called by muse, mutect2
- SPINK5 | c.2323G>C p.D775H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV56260067; called by muse, mutect2, varscan2
- SPOPL | c.274A>C p.S92R | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV54515307; called by muse, mutect2
- SQLE | c.254del p.P85Lfs*25 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | catalogued as rs760774524; called by mutect2, pindel, varscan2
- SRARP | c.159G>T p.K53N | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs767567673, COSV61497953; called by muse, mutect2
- SYT9 | c.1340T>A p.V447E | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV59623050; called by muse, mutect2, varscan2
- TBC1D23 | c.950G>T p.C317F | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61369700; called by muse, mutect2, varscan2
- TENM2 | c.4218C>A p.S1406R (on ENST00000518659 / NM_001122679.2; = p.S1167R on NM_001080428.3) | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.979); catalogued as COSV69137970; called by muse, mutect2, varscan2
- TMEM200B | c.672C>A p.Y224* | Nonsense Mutation (SNP) | VAF 3/28 reads (11%) | catalogued as COSV58051934; called by muse, mutect2
- TMEM270 | c.218T>A p.L73Q | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV57639423; called by muse, mutect2
- TMEM67 | c.2460del p.G821Vfs*19 | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | catalogued as CM090683; called by mutect2, pindel, varscan2
- TNN | c.2155G>A p.V719M | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53432620, COSV99510881; called by muse, mutect2, varscan2
- TTC37 | c.3562A>T p.S1188C | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV62456197; called by muse, mutect2, varscan2
- ULK1 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV58859139; called by muse, mutect2, varscan2
- UNC45B | c.2145G>T p.R715= | Splice Region (SNP) | VAF 5/42 reads (12%) | catalogued as COSV52099232, COSV99268999; called by muse, mutect2, varscan2
- VPS13A | c.8568G>T p.M2856I | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62435831; called by muse, mutect2, varscan2
- ZBBX | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV56793515, COSV56797375; called by muse, mutect2, varscan2
- ZDHHC15 | c.698A>C p.Y233S | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64903076; called by muse, mutect2
- ZNF182 | c.1113G>T p.K371N | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.531); catalogued as COSV59358982; called by muse, mutect2
- ZNF208 | c.2596T>C p.C866R | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV68110889; called by muse, mutect2, varscan2
- ZNF433 | c.400T>C p.Y134H | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV61399996; called by muse, mutect2
- ZNF451 | c.2456G>T p.S819I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV62599204; called by muse, mutect2, varscan2
- ZNF600 | c.2015A>T p.D672V | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV57744363; called by muse, mutect2, varscan2
- ZNF655 | c.974A>G p.H325R | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53159684; called by muse, mutect2, varscan2
- CNOT1 | c.583_602del p.A195Tfs*7 | Frame Shift Del (DEL) | VAF 64/360 reads (18%) | called by mutect2, pindel, varscan2
- DYNLL1 | c.222_225del p.Y75Sfs*34 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel*
- ZNF142 | c.3380del p.P1127Hfs*90 (on ENST00000411696 / NM_001379660.1; = p.P927Hfs*90 on NM_001105537.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 29/204 reads (14%) | called by mutect2, pindel, varscan2
- AASDH | c.1374T>C p.L458= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV52709129; called by muse, mutect2
- AGTR1 | c.150G>A p.V50= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV100837105; called by muse, mutect2, varscan2
- AQP12B | c.168G>T p.G56= (on ENST00000621682; = p.G68= on NM_001102467.2) | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV68184318; called by muse, mutect2, varscan2
- BRINP3 | c.2217G>C p.V739= | Silent (SNP) | VAF 12/121 reads (10%) | catalogued as COSV66531088, COSV66535712; called by muse, mutect2, varscan2
- CDON | c.864T>C p.Y288= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV55000863; called by muse, mutect2, varscan2
- CSMD1 | c.6471C>A p.T2157= (on ENST00000520002; = p.T2156= on NM_033225.6) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV59363307; called by muse, mutect2, varscan2
- DSP | c.6738T>A p.V2246= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV65794611; called by muse, mutect2, varscan2
- EFCAB5 | c.2838C>T p.L946= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV57932526, COSV57934655; called by muse, mutect2
- GPNMB | c.240G>A p.A80= | Silent (SNP) | VAF 16/135 reads (12%) | catalogued as rs149206943; called by muse, mutect2, varscan2
- GUCY2D | c.1854C>T p.V618= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV54697945; called by muse, mutect2, varscan2
- HSPG2 | c.7893G>A p.P2631= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs571876580, COSV65975390; called by muse, mutect2, varscan2
- IGKV1-17 | c.138G>T p.R46= | Silent (SNP) | VAF 22/228 reads (10%) | called by muse, mutect2, varscan2
- KCNS2 | c.1170T>A p.T390= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV54640168; called by muse, mutect2, varscan2
- KIF2B | c.234G>A p.L78= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as COSV52134053; called by muse, mutect2
- MYO18B | c.2454C>T p.S818= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs368897377; called by muse, mutect2
- MYO9A | c.4695C>G p.T1565= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs200475088, COSV61855392; called by muse, mutect2, varscan2
- MYOM1 | c.2325G>T p.A775= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV55292482; called by mutect2, varscan2
- NLRP10 | c.1776T>C p.N592= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV60781781; called by muse, mutect2, varscan2
- NQO1 | c.822A>G p.K274= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as COSV57732482; called by muse, mutect2, varscan2
- OR10V1 | c.669G>T p.V223= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV100276148; called by muse, mutect2, varscan2
- OR2T11 | c.162C>A p.T54= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV58186786; called by muse, mutect2, varscan2
- OR8S1 | c.327G>T p.G109= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as rs762481688, COSV100043671, COSV59600719; called by muse, mutect2, varscan2
- P2RY10 | c.654C>A p.T218= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV50684400; called by muse, mutect2, varscan2
- PAPPA2 | c.858G>T p.A286= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100866629, COSV62785865, COSV62789208; called by muse, mutect2
- PCDHB2 | c.657C>G p.G219= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV52035339, COSV52036061; called by muse, mutect2, varscan2
- PCDHB9 | c.1323C>A p.V441= | Silent (SNP) | VAF 40/208 reads (19%) | catalogued as COSV53382244; called by muse, mutect2, varscan2
- PDE3A | c.3291A>T p.A1097= | Silent (SNP) | VAF 6/116 reads (5%) | catalogued as COSV62979720; called by muse, mutect2
- PRMT8 | c.462G>A p.K154= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as rs267603447, COSV54213952; called by muse, mutect2, varscan2
- RAPGEF6 | c.4023G>T p.S1341= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as rs764135751, COSV57253198; called by muse, mutect2, varscan2
- RGS7 | c.1182C>G p.P394= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as COSV100468583, COSV58548022; called by muse, mutect2, varscan2
- RIMS2 | c.3273A>T p.T1091= (on ENST00000666250 / NM_001348490.2; = p.T899= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV51709822; called by muse, mutect2, varscan2
- SCPEP1 | c.762G>T p.G254= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV51855221; called by muse, mutect2, varscan2
- SLC17A1 | c.996C>T p.S332= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs757219937, COSV55080188, COSV99765946; called by muse, mutect2, varscan2
- SLC39A12 | c.1917G>T p.G639= (on ENST00000377369 / NM_001145195.2; = p.G602= on NM_152725.3) | Silent (SNP) | VAF 20/128 reads (16%) | catalogued as COSV66201367; called by muse, mutect2, varscan2
- SLC3A1 | c.1845C>G p.P615= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as rs757852597, COSV53218495; called by muse, mutect2
- SOS1 | c.2160A>T p.T720= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as COSV67676912; called by muse, mutect2, varscan2
- SPRTN | c.87G>T p.L29= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as COSV50479181; called by muse, mutect2, varscan2
- SSMEM1 | c.126G>T p.L42= | Silent (SNP) | VAF 24/140 reads (17%) | catalogued as COSV52834150, COSV52834751; called by muse, mutect2, varscan2
- SUGP2 | c.2520A>T p.S840= | Silent (SNP) | VAF 8/120 reads (7%) | catalogued as COSV58263093; called by muse, mutect2
- TRPV5 | c.981G>T p.P327= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs760393955, COSV54687769, COSV99520825; called by muse, mutect2, varscan2
- TSHZ3 | c.2238C>T p.P746= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV99552251, COSV99552317; called by muse, mutect2, varscan2
- TTN | c.16608A>T p.T5536= (on ENST00000591111; = p.T4609= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as COSV60250251; called by muse, mutect2
- TUBB4A | c.574C>T p.L192= | Silent (SNP) | VAF 36/180 reads (20%) | catalogued as rs1384837003, COSV51161986; called by muse, mutect2, varscan2
- ZNF43 | c.1656C>A p.I552= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV61685260; called by muse, mutect2, varscan2
- H2BP2 | n.1062-335G>A | Intron (SNP) | VAF 16/224 reads (7%) | catalogued as rs587678648; called by muse, mutect2
